Somatic mutation profile of tumor specimen TCGA-HC-7740-01B (aliquot TCGA-HC-7740-01B-04D-2298-08) from TCGA case TCGA-HC-7740, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.9 years (21,883 days).
Specimen TCGA-HC-7740-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2ee960a-73d9-4645-bf16-81dcd718dd49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7740-10A (Blood Derived Normal), aliquot TCGA-HC-7740-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/632efb94-12d9-4719-bb4a-f9b132816617

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.6778G>A p.G2260S | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs192587828, COSV99778504; called by muse, mutect2
- GRIN2A | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100410155, COSV58027171; called by muse, mutect2, varscan2
- HHAT | c.647A>C p.N216T | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV54810667, COSV54810902; called by muse, mutect2
- IL1RAPL2 | c.762T>A p.D254E | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs1198584195, COSV61185251; called by muse, mutect2
- MRTFB | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57962205; called by muse, mutect2, varscan2
- NSD3 | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | catalogued as COSV57674555; called by muse, mutect2
- PROS1 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62399803; called by muse, mutect2, varscan2
- PTPN9 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV60726213; called by muse, mutect2
- SMARCC2 | c.3529G>C p.V1177L | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV53240987; called by muse, mutect2
- SPEN | c.9566A>G p.Y3189C | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65367875; called by muse, mutect2, varscan2
- TIGD5 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55309419; called by muse, mutect2
- CASP14 | c.515T>A p.V172E | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); called by muse, mutect2
- FARP2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IFT172 | c.4563T>G p.S1521R | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.23); called by muse, mutect2
- TTN | c.73877G>A p.R24626K (on ENST00000591111; = p.R17202K on NM_003319.4) | Missense Mutation (SNP) | VAF 33/669 reads (5%) | PolyPhen benign (0.023); called by muse, mutect2
- HPS5 | c.2277A>G p.G759= (on ENST00000349215 / NM_181507.2; = p.G645= on NM_007216.4) | Silent (SNP) | VAF 23/312 reads (7%) | catalogued as rs752195294, COSV61688098; called by muse, mutect2
- MYOM3 | c.960G>A p.K320= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV58401680; called by muse, mutect2
- RYR1 | c.369C>T p.S123= | Silent (SNP) | VAF 31/334 reads (9%) | catalogued as COSV62112163; called by muse, mutect2
- ZHX3 | c.1374C>T p.P458= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV58389004; called by muse, mutect2
- PTPRN | c.2675+842A>G | Intron (SNP) | VAF 18/128 reads (14%) | catalogued as COSV55351644; called by muse, mutect2, varscan2
